Somatic mutation profile of tumor specimen TCGA-CQ-5334-01A (aliquot TCGA-CQ-5334-01A-01D-1683-08) from TCGA case TCGA-CQ-5334, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Cheek mucosa; AJCC pathologic stage: Stage IVA; Tumor grade: G2; Age at diagnosis: 87.7 years (32,024 days).
Specimen TCGA-CQ-5334-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 15768b97-daca-4544-9d5d-c047b4f9ffe8.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-CQ-5334-10A (Blood Derived Normal), aliquot TCGA-CQ-5334-10A-01D-1683-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/6069a279-376c-4cc6-ba15-5e9d121c5a15

The open-access MAF lists 195 somatic variants for this specimen: 150 protein-altering or splice-affecting, 42 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 123, Silent 42, Nonsense Mutation 12, Frame Shift Del 6, Frame Shift Ins 4, Splice Region 2, Splice Site 1, Translation Start Site 1, 3'Flank 1, RNA 1, In Frame Del 1, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CTCF | c.1342C>T p.R448* | Nonsense Mutation (SNP) | VAF 5/35 reads (14%) | hotspot (GDC flag); catalogued as rs769948988, COSV50461776; called by muse, mutect2
- MAPK1 | c.964G>A p.E322K | Missense Mutation (SNP) | VAF 11/67 reads (16%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs1057519911, COSV53184855, COSV99308005; ClinVar: likely pathogenic; called by muse, mutect2
- TP53 | c.497C>G p.S166* | Nonsense Mutation (SNP) | VAF 14/62 reads (23%) | catalogued as rs1555526101, COSV52661795, COSV52683537, COSV52718793; ClinVar: pathogenic; called by muse, varscan2
- TP53 | c.473G>A p.R158H | Missense Mutation (SNP) | VAF 7/67 reads (10%) | hotspot (GDC flag); SIFT tolerated (0.1); PolyPhen possibly damaging (0.45); catalogued as rs587782144, CM102353, CM165595, CM994513, COSV52676395, COSV52678258, COSV52680378, COSV53545833; ClinVar: pathogenic / likely pathogenic; called by muse, varscan2
- ABCA1 | c.4274C>T p.P1425L | Missense Mutation (SNP) | VAF 11/39 reads (28%) | SIFT tolerated (0.22); PolyPhen benign (0.005); catalogued as rs755825383, COSV101036594, COSV101037169; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ACAD8 | c.396G>A p.M132I | Missense Mutation (SNP) | VAF 12/31 reads (39%) | SIFT tolerated (0.09); PolyPhen benign (0.015); catalogued as COSV99844123; called by muse, varscan2
- ACVR1 | c.1273G>C p.E425Q | Missense Mutation (SNP) | VAF 16/101 reads (16%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.991); catalogued as COSV99717528; called by muse, mutect2, varscan2
- ADGRB1 | c.1929G>C p.Q643H | Missense Mutation (SNP) | VAF 16/85 reads (19%) | SIFT tolerated (0.35); PolyPhen probably damaging (0.995); catalogued as COSV60101641; called by muse, mutect2, varscan2
- ADGRL1 | c.3808C>T p.R1270* (on ENST00000340736 / NM_001008701.3; = p.R1265* on NM_014921.5) | Nonsense Mutation (SNP) | VAF 14/72 reads (19%) | catalogued as COSV100529293, COSV61566728; called by muse, mutect2, varscan2
- AHSA1 | c.477C>A p.F159L | Missense Mutation (SNP) | VAF 13/40 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV99375773; called by muse, mutect2, varscan2
- ARHGAP32 | c.2119G>C p.E707Q (on ENST00000310343 / NM_001378025.1; = p.E358Q on NM_014715.4) | Missense Mutation (SNP) | VAF 23/114 reads (20%) | SIFT deleterious (0); PolyPhen benign (0.393); catalogued as COSV100087028, COSV59852061; called by muse, mutect2, varscan2
- ARMC9 | c.417G>C p.L139F | Missense Mutation (SNP) | VAF 22/121 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); catalogued as COSV100589526; called by muse, mutect2, varscan2
- ATF5 | c.776G>A p.R259H | Missense Mutation (SNP) | VAF 6/34 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs748077258, COSV100351809; called by muse, mutect2, varscan2
- BCL9 | c.1045G>A p.D349N | Missense Mutation (SNP) | VAF 17/101 reads (17%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.761); catalogued as rs781863100, COSV99324547; called by muse, mutect2, varscan2
- BPIFB6 | c.118G>A p.E40K | Missense Mutation (SNP) | VAF 11/68 reads (16%) | SIFT deleterious (0.03); PolyPhen benign (0.433); catalogued as rs1392111589, COSV100848488; called by muse, mutect2, varscan2
- BRD8 | c.1519G>A p.E507K (on ENST00000254900 / NM_139199.2; = p.E580K on NM_006696.4) | Missense Mutation (SNP) | VAF 20/111 reads (18%) | SIFT deleterious (0.04); PolyPhen benign (0.078); catalogued as COSV99136635; called by muse, mutect2, varscan2
- CACNA1D | c.2750C>T p.T917M (on ENST00000350061 / NM_001128840.3; = p.T937M on NM_000720.4) | Missense Mutation (SNP) | VAF 7/41 reads (17%) | SIFT tolerated (0.23); PolyPhen benign (0.172); catalogued as rs145327253; called by muse, mutect2
- CACNA1D | c.5628C>G p.I1876M (on ENST00000350061 / NM_001128840.3; = p.I1896M on NM_000720.4) | Missense Mutation (SNP) | VAF 16/57 reads (28%) | SIFT tolerated, low confidence (0.28); PolyPhen benign (0); catalogued as COSV99856747; called by muse, mutect2, varscan2
- CASP8 | c.1A>G p.M1? | Translation Start Site (SNP) | VAF 8/39 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.877); catalogued as COSV51856572; called by muse, mutect2, varscan2
- CCDC91 | c.191C>G p.S64C | Missense Mutation (SNP) | VAF 37/188 reads (20%) | SIFT tolerated (0.08); PolyPhen benign (0.007); catalogued as COSV100081380, COSV60338563; called by muse, mutect2, varscan2
- CCNA1 | c.128A>G p.E43G | Missense Mutation (SNP) | VAF 24/122 reads (20%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.104); catalogued as COSV99714364; called by muse, mutect2, varscan2
- CD163L1 | c.3436G>A p.E1146K | Missense Mutation (SNP) | VAF 30/227 reads (13%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.724); catalogued as COSV100549926, COSV58016152; called by muse, mutect2, varscan2
- CD1E | c.698C>T p.S233L | Missense Mutation (SNP) | VAF 7/64 reads (11%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.905); catalogued as rs201152862, COSV100936921; called by muse, mutect2, varscan2
- CELSR3 | c.8380G>A p.E2794K | Missense Mutation (SNP) | VAF 22/89 reads (25%) | SIFT deleterious (0.01); PolyPhen benign (0.106); catalogued as rs1466590842, COSV99372693; called by muse, mutect2, varscan2
- CENPF | c.5861C>T p.S1954L | Missense Mutation (SNP) | VAF 12/69 reads (17%) | SIFT tolerated (0.6); PolyPhen benign (0.03); catalogued as rs1257572014, COSV65276163; called by muse, mutect2, varscan2
- CES2 | c.406G>C p.E136Q | Missense Mutation (SNP) | VAF 27/127 reads (21%) | SIFT deleterious (0.02); PolyPhen benign (0.178); catalogued as COSV100399083; called by muse, mutect2, varscan2
- CETP | c.1182G>C p.K394N | Missense Mutation (SNP) | VAF 23/97 reads (24%) | SIFT tolerated (0.08); PolyPhen benign (0.109); catalogued as COSV52361351, COSV99569876; called by muse, mutect2, varscan2
- CLCNKA | c.2010G>C p.W670C | Missense Mutation (SNP) | VAF 30/182 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as COSV100509894; called by muse, mutect2, varscan2
- CNKSR3 | c.1468G>A p.E490K | Missense Mutation (SNP) | VAF 17/98 reads (17%) | SIFT tolerated (0.4); PolyPhen benign (0.125); catalogued as rs764194390, COSV101401297; called by muse, mutect2, varscan2
- CREB5 | c.910C>G p.Q304E (on ENST00000357727 / NM_182898.4; = p.Q297E on NM_004904.3) | Missense Mutation (SNP) | VAF 11/37 reads (30%) | SIFT tolerated (0.4); PolyPhen benign (0.015); catalogued as COSV100744230, COSV100745907; called by muse, mutect2
- CRTC3 | c.1387C>T p.R463C | Missense Mutation (SNP) | VAF 16/77 reads (21%) | SIFT tolerated (0.08); PolyPhen benign (0); catalogued as rs193921108, COSV51601061, COSV99185629; called by muse, mutect2, varscan2
- CSMD2 | c.9337G>C p.D3113H | Missense Mutation (SNP) | VAF 17/135 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as COSV99586634; called by muse, mutect2, varscan2
- CUL9 | c.4660G>A p.D1554N | Missense Mutation (SNP) | VAF 44/273 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99056035, COSV99334858; called by muse, mutect2, varscan2
- CYB5R3 | c.670G>A p.E224K | Missense Mutation (SNP) | VAF 26/88 reads (30%) | SIFT tolerated (0.16); PolyPhen benign (0.088); catalogued as COSV61546989; called by muse, mutect2, varscan2
- DEPDC1 | c.937G>C p.D313H | Missense Mutation (SNP) | VAF 13/85 reads (15%) | SIFT tolerated (0.06); PolyPhen benign (0.079); catalogued as COSV100920215; called by muse, mutect2, varscan2
- DGKA | c.832G>T p.E278* | Nonsense Mutation (SNP) | VAF 20/114 reads (18%) | catalogued as COSV100092701; called by muse, mutect2, varscan2
- DHRS2 | c.44C>T p.P15L | Missense Mutation (SNP) | VAF 44/124 reads (35%) | SIFT tolerated (0.08); PolyPhen benign (0); catalogued as rs771504271, COSV99158782; called by muse, mutect2, varscan2
- EIF2A | c.1312G>C p.E438Q | Missense Mutation (SNP) | VAF 19/85 reads (22%) | SIFT tolerated (0.93); PolyPhen benign (0.001); catalogued as COSV99855776; called by muse, mutect2, varscan2
- EPHA10 | c.679G>A p.E227K | Missense Mutation (SNP) | VAF 10/24 reads (42%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.996); catalogued as rs868136274, COSV57621521, COSV57628166; called by muse, mutect2, varscan2
- EPHA2 | c.1312+1G>T p.X438_splice | Splice Site (SNP) | VAF 27/62 reads (44%) | catalogued as COSV100626030; called by muse, mutect2, varscan2
- EPHA3 | c.1043C>T p.P348L | Missense Mutation (SNP) | VAF 15/55 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100343274; called by muse, mutect2, varscan2
- ERBB3 | c.1259G>C p.G420A | Missense Mutation (SNP) | VAF 8/36 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV57248073, COSV57251829, COSV57254433; called by muse, mutect2, varscan2
- FAM126B | c.1205C>T p.S402L | Missense Mutation (SNP) | VAF 6/40 reads (15%) | SIFT tolerated (0.31); PolyPhen benign (0.01); catalogued as COSV99627416; called by muse, varscan2
- FAM126B | c.1148C>T p.S383L | Missense Mutation (SNP) | VAF 8/45 reads (18%) | SIFT tolerated (0.36); PolyPhen benign (0); catalogued as COSV99627418; called by muse, varscan2
- FARSB | c.789A>C p.A263= | Splice Region (SNP) | VAF 11/54 reads (20%) | catalogued as COSV99918191; called by muse, mutect2, varscan2
- FGD6 | c.3301C>G p.R1101G | Missense Mutation (SNP) | VAF 10/52 reads (19%) | SIFT tolerated (0.23); PolyPhen probably damaging (1); catalogued as COSV100676394; called by muse, mutect2, varscan2
- FGF8 | c.509C>T p.A170V (on ENST00000344255 / NM_033164.4; = p.A152V on NM_006119.6) | Missense Mutation (SNP) | VAF 9/47 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); catalogued as COSV100199321; called by muse, mutect2, varscan2
- FHOD3 | c.541G>A p.G181R | Missense Mutation (SNP) | VAF 12/59 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV99940298; called by muse, varscan2
- FNBP1 | c.808G>A p.E270K | Missense Mutation (SNP) | VAF 13/67 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.668); catalogued as COSV100852576; called by muse, varscan2
- FNIP2 | c.1576C>T p.R526C | Missense Mutation (SNP) | VAF 20/98 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100032062, COSV52443177; called by muse, mutect2, varscan2
- GCM2 | c.386C>G p.P129R | Missense Mutation (SNP) | VAF 18/37 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); catalogued as rs761079176, COSV101069441; called by muse, mutect2, varscan2
- GNAT1 | c.190G>C p.E64Q | Missense Mutation (SNP) | VAF 19/73 reads (26%) | SIFT tolerated (1); PolyPhen probably damaging (0.956); catalogued as COSV99137225; called by muse, mutect2, varscan2
- GPRIN1 | c.1128G>C p.K376N | Missense Mutation (SNP) | VAF 11/64 reads (17%) | SIFT deleterious (0.01); PolyPhen benign (0.276); catalogued as COSV99991101; called by muse, mutect2, varscan2
- GTF2I | c.427C>T p.R143* | Nonsense Mutation (SNP) | VAF 11/92 reads (12%) | catalogued as rs1064765, COSV100259463; called by muse, mutect2, varscan2
- H3C12 | c.32C>A p.S11Y | Missense Mutation (SNP) | VAF 6/57 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.544); catalogued as COSV100377486; called by muse, mutect2
- HADHB | c.894G>T p.K298N | Missense Mutation (SNP) | VAF 21/113 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV100501890; called by muse, mutect2, varscan2
- HADHB | c.895C>A p.P299T | Missense Mutation (SNP) | VAF 20/111 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.982); catalogued as COSV100501893; called by muse, mutect2, varscan2
- HECTD1 | c.5380G>C p.E1794Q | Missense Mutation (SNP) | VAF 22/79 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.932); catalogued as COSV101237307; called by muse, mutect2, varscan2
- HMGN2 | c.250G>A p.E84K | Missense Mutation (SNP) | VAF 15/87 reads (17%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.587); catalogued as COSV100751469, COSV63525167; called by muse, mutect2, varscan2
- HUWE1 | c.10912A>G p.I3638V | Missense Mutation (SNP) | VAF 3/10 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.558); catalogued as COSV104394396, COSV99470812; called by muse, mutect2
- IFIT3 | c.619C>T p.Q207* | Nonsense Mutation (SNP) | VAF 12/49 reads (24%) | catalogued as COSV99259914; called by muse, mutect2, varscan2
- IGF1R | c.508G>T p.V170L | Missense Mutation (SNP) | VAF 10/115 reads (9%) | SIFT tolerated (0.11); PolyPhen benign (0.001); catalogued as rs1419820249, COSV51270250, COSV99149083; called by muse, mutect2
- IGSF8 | c.1010G>A p.R337H | Missense Mutation (SNP) | VAF 8/35 reads (23%) | SIFT tolerated (0.32); PolyPhen benign (0); catalogued as rs200398989, COSV100081527; called by muse, mutect2
- ITGA11 | c.150C>G p.I50M | Missense Mutation (SNP) | VAF 4/16 reads (25%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.825); catalogued as COSV100240991, COSV100242302; called by muse, mutect2
- ITGB1 | c.1120G>T p.A374S | Missense Mutation (SNP) | VAF 10/65 reads (15%) | SIFT deleterious (0.02); PolyPhen benign (0.147); catalogued as COSV100171317; called by muse, varscan2
- ITPRID1 | c.2195G>T p.G732V | Missense Mutation (SNP) | VAF 15/85 reads (18%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.839); catalogued as COSV100085767, COSV60077562; called by muse, mutect2, varscan2
- LOXL3 | c.1082G>A p.R361H | Missense Mutation (SNP) | VAF 36/185 reads (19%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.841); catalogued as rs765857380, COSV51207024; called by muse, mutect2, varscan2
- LRP1B | c.11344G>T p.D3782Y | Missense Mutation (SNP) | VAF 23/84 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.987); catalogued as rs1430555496, COSV101253385, COSV67223762; called by muse, mutect2, varscan2
- LRRC36 | c.2131G>A p.E711K | Missense Mutation (SNP) | VAF 14/60 reads (23%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.187); catalogued as rs1380489337, COSV99338447; called by muse, mutect2, varscan2
- LY9 | c.1847C>G p.S616C | Missense Mutation (SNP) | VAF 38/148 reads (26%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.473); catalogued as COSV99626274; called by muse, mutect2, varscan2
- MAPK6 | c.1471G>A p.G491S | Missense Mutation (SNP) | VAF 6/28 reads (21%) | SIFT tolerated, low confidence (0.58); PolyPhen benign (0.015); catalogued as rs1394273765, COSV99958934; called by muse, mutect2, varscan2
- MCM9 | c.560C>G p.S187* | Nonsense Mutation (SNP) | VAF 14/76 reads (18%) | catalogued as rs1427252745, COSV60164889, COSV60165062; called by muse, mutect2, varscan2
- MITF | c.1258G>A p.V420I (on ENST00000448226 / NM_006722.3; = p.V320I on NM_000248.4) | Missense Mutation (SNP) | VAF 14/61 reads (23%) | SIFT tolerated (0.4); PolyPhen benign (0.041); catalogued as rs757354709, COSV58831102; called by muse, mutect2, varscan2
- MYO1G | c.2080C>T p.R694C | Missense Mutation (SNP) | VAF 11/51 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs576689841, COSV51857463; called by muse, mutect2, varscan2
- MYRF | c.1256C>T p.T419M (on ENST00000278836 / NM_001127392.3; = p.T410M on NM_013279.4) | Missense Mutation (SNP) | VAF 5/26 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs193921094, COSV53886090, COSV53887127; ClinVar: uncertain significance; called by muse, mutect2
- N4BP2L1 | c.511C>T p.R171* | Nonsense Mutation (SNP) | VAF 18/85 reads (21%) | catalogued as rs1244495987, COSV58412418; called by muse, mutect2, varscan2
- NKAIN2 | c.195T>C p.Y65= | Splice Region (SNP) | VAF 30/186 reads (16%) | catalogued as COSV100862484; called by muse, mutect2, varscan2
- NOTCH1 | c.3355G>T p.G1119* | Nonsense Mutation (SNP) | VAF 10/39 reads (26%) | catalogued as COSV99485741; called by muse, mutect2, varscan2
- NOTCH4 | c.4586C>G p.S1529* | Nonsense Mutation (SNP) | VAF 6/35 reads (17%) | catalogued as COSV100900417; called by muse, mutect2, varscan2
- OR2L13 | c.528C>A p.F176L | Missense Mutation (SNP) | VAF 27/174 reads (16%) | SIFT deleterious (0); PolyPhen benign (0.218); catalogued as rs865885102, COSV63551813, COSV63556626; called by muse, mutect2, varscan2
- PACS2 | c.1559C>T p.S520F | Missense Mutation (SNP) | VAF 8/26 reads (31%) | SIFT tolerated (0.1); PolyPhen benign (0.21); catalogued as rs1555412447, COSV100330613; called by muse, mutect2, varscan2
- PACSIN3 | c.832G>A p.E278K | Missense Mutation (SNP) | VAF 55/169 reads (33%) | SIFT tolerated (0.1); PolyPhen benign (0.011); catalogued as rs772870340, COSV100096056; called by muse, mutect2, varscan2
- PADI4 | c.1143C>G p.I381M | Missense Mutation (SNP) | VAF 9/35 reads (26%) | SIFT tolerated (0.55); PolyPhen possibly damaging (0.621); catalogued as COSV100966707, COSV64923820; called by muse, mutect2, varscan2
- PAQR5 | c.527A>G p.Q176R | Missense Mutation (SNP) | VAF 8/75 reads (11%) | SIFT tolerated (0.05); PolyPhen benign (0.013); catalogued as rs1458160220, COSV100575392; called by muse, mutect2, varscan2
- PCNT | c.5978T>A p.V1993D | Missense Mutation (SNP) | VAF 11/47 reads (23%) | SIFT tolerated (0.62); PolyPhen benign (0); catalogued as COSV100855083; called by muse, mutect2, varscan2
- PFAS | c.872G>A p.R291Q | Missense Mutation (SNP) | VAF 8/42 reads (19%) | SIFT tolerated (0.66); PolyPhen benign (0.001); catalogued as rs747458224, COSV100118783; called by muse, mutect2, varscan2
- PHF1 | c.979T>A p.C327S | Missense Mutation (SNP) | VAF 26/150 reads (17%) | SIFT deleterious (0.02); PolyPhen benign (0.354); catalogued as COSV100992575; called by muse, mutect2, varscan2
- PHF20 | c.141C>G p.F47L | Missense Mutation (SNP) | VAF 15/99 reads (15%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.755); catalogued as COSV100179909; called by muse, mutect2, varscan2
- PHF6 | c.784G>A p.D262N (on ENST00000332070 / NM_032458.3; = p.D263N on NM_032335.3) | Missense Mutation (SNP) | VAF 14/32 reads (44%) | SIFT tolerated (1); PolyPhen benign (0.007); catalogued as COSV100136266, COSV100136354; called by muse, mutect2, varscan2
- PIKFYVE | c.3777G>C p.E1259D | Missense Mutation (SNP) | VAF 9/39 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.952); catalogued as COSV100009941; called by muse, mutect2, varscan2
- PLCL1 | c.890G>A p.R297H | Missense Mutation (SNP) | VAF 20/96 reads (21%) | SIFT tolerated (0.29); PolyPhen benign (0.01); catalogued as rs140990771; called by muse, mutect2, varscan2
- PLOD3 | c.2089G>A p.D697N | Missense Mutation (SNP) | VAF 7/27 reads (26%) | SIFT tolerated (1); PolyPhen benign (0.006); catalogued as rs199647243, COSV99777840; called by mutect2, varscan2
- PPP2R5D | c.791G>A p.R264H | Missense Mutation (SNP) | VAF 22/122 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs764831855, COSV55151522; called by muse, mutect2, varscan2
- PPP4C | c.160G>A p.D54N | Missense Mutation (SNP) | VAF 4/54 reads (7%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.616); catalogued as COSV54222859; called by muse, mutect2
- PPP4R3B | c.866C>T p.S289F | Missense Mutation (SNP) | VAF 11/51 reads (22%) | SIFT deleterious (0); PolyPhen benign (0.169); catalogued as COSV99701476; called by muse, mutect2, varscan2
- PTH1R | c.236G>A p.R79K | Missense Mutation (SNP) | VAF 11/35 reads (31%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV100480843; called by muse, mutect2, varscan2
- RABEP1 | c.1305C>A p.D435E | Missense Mutation (SNP) | VAF 9/57 reads (16%) | SIFT deleterious (0.04); PolyPhen benign (0.013); catalogued as COSV52584656, COSV99336338; called by muse, mutect2, varscan2
- RIC8B | c.907G>C p.E303Q | Missense Mutation (SNP) | VAF 9/51 reads (18%) | SIFT tolerated (0.27); PolyPhen benign (0.243); catalogued as COSV100822454; called by muse, mutect2, varscan2
- RPL17-C18orf32 | c.328G>C p.D110H | Missense Mutation (SNP) | VAF 11/38 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.979); catalogued as COSV100271478; called by muse, mutect2, varscan2
- RPL31 | c.283G>A p.D95N | Missense Mutation (SNP) | VAF 9/43 reads (21%) | SIFT tolerated (0.05); PolyPhen benign (0.163); catalogued as COSV99961386; called by muse, mutect2, varscan2
- RUNDC1 | c.1765C>T p.R589C | Missense Mutation (SNP) | VAF 10/33 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs375753180; called by muse, mutect2, varscan2
- RYR1 | c.10882C>T p.R3628C | Missense Mutation (SNP) | VAF 16/50 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV62088497; called by muse, mutect2, varscan2
- S100A3 | c.284C>G p.S95* | Nonsense Mutation (SNP) | VAF 22/120 reads (18%) | catalogued as COSV100573022, COSV99056353; called by muse, varscan2
- S100A3 | c.233C>G p.S78* | Nonsense Mutation (SNP) | VAF 25/138 reads (18%) | catalogued as COSV100573023; called by muse, varscan2
- SERINC3 | c.1061G>A p.R354H | Missense Mutation (SNP) | VAF 13/80 reads (16%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.597); catalogued as rs750431207, COSV99667595; called by muse, mutect2, varscan2
- SH3BP2 | c.934C>T p.H312Y | Missense Mutation (SNP) | VAF 16/101 reads (16%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.091); catalogued as COSV100696871; called by muse, mutect2, varscan2
- SLC25A10 | c.742G>A p.G248R | Missense Mutation (SNP) | VAF 62/286 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs763212617, COSV100518945; called by muse, mutect2, varscan2
- SLC25A46 | c.940T>C p.F314L | Missense Mutation (SNP) | VAF 46/240 reads (19%) | SIFT tolerated (0.2); PolyPhen probably damaging (0.932); catalogued as COSV100582513; called by muse, mutect2, varscan2
- SLC41A3 | c.109G>A p.D37N | Missense Mutation (SNP) | VAF 27/136 reads (20%) | SIFT tolerated (0.33); PolyPhen benign (0.107); catalogued as COSV100259383; called by muse, mutect2, varscan2
- SLC6A5 | c.1795C>T p.R599C | Missense Mutation (SNP) | VAF 27/91 reads (30%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.982); catalogued as rs755102755, COSV54232374; called by muse, mutect2, varscan2
- SLC7A5 | c.793G>A p.E265K | Missense Mutation (SNP) | VAF 14/95 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99879004; called by muse, mutect2, varscan2
- SLCO1B3 | c.604G>C p.E202Q | Missense Mutation (SNP) | VAF 8/52 reads (15%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.643); catalogued as COSV99680887; called by muse, mutect2
- SMC1A | c.897C>G p.I299M | Missense Mutation (SNP) | VAF 15/31 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV100447066; called by muse, mutect2, varscan2
- SON | c.3560C>T p.S1187L | Missense Mutation (SNP) | VAF 21/108 reads (19%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.957); catalogued as COSV99277031; called by muse, mutect2, varscan2
- SPEG | c.5089C>T p.R1697W | Missense Mutation (SNP) | VAF 6/39 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV100403427; called by muse, mutect2, varscan2
- SPPL2C | c.1503G>T p.L501F | Missense Mutation (SNP) | VAF 20/115 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs902465528, COSV100233947; called by muse, mutect2, varscan2
- SREBF2 | c.1022G>A p.R341Q | Missense Mutation (SNP) | VAF 6/33 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs767557693, COSV63330427; called by muse, mutect2, varscan2
- ST6GAL2 | c.84C>G p.I28M | Missense Mutation (SNP) | VAF 7/32 reads (22%) | PolyPhen benign (0.391); catalogued as COSV100867694, COSV64526162; called by muse, mutect2, varscan2
- SYNE2 | c.12016G>A p.E4006K | Missense Mutation (SNP) | VAF 32/94 reads (34%) | SIFT tolerated (0.09); PolyPhen benign (0.058); catalogued as COSV100646822; called by muse, mutect2, varscan2
- SYNGAP1 | c.639C>G p.I213M | Missense Mutation (SNP) | VAF 24/71 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.88); catalogued as COSV99537912; called by muse, mutect2, varscan2
- TARS1 | c.448C>G p.Q150E | Missense Mutation (SNP) | VAF 29/119 reads (24%) | SIFT deleterious (0.01); PolyPhen benign (0.019); catalogued as COSV99465529; called by muse, mutect2, varscan2
- TENT4A | c.1018A>G p.I340V | Missense Mutation (SNP) | VAF 21/49 reads (43%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.449); catalogued as COSV100048683; called by muse, mutect2, varscan2
- TMED6 | c.326C>G p.S109C | Missense Mutation (SNP) | VAF 35/186 reads (19%) | SIFT tolerated (0.13); PolyPhen benign (0.432); catalogued as COSV55342196; called by muse, mutect2, varscan2
- TMEM131 | c.1306G>C p.D436H | Missense Mutation (SNP) | VAF 6/30 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99486688, COSV99488206; called by muse, mutect2
- TMEM132B | c.3037C>T p.P1013S | Missense Mutation (SNP) | VAF 5/31 reads (16%) | SIFT tolerated (0.24); PolyPhen benign (0.027); catalogued as COSV100168716; called by mutect2, varscan2
- TMEM59 | c.213G>C p.Q71H | Missense Mutation (SNP) | VAF 12/72 reads (17%) | SIFT tolerated (0.41); PolyPhen probably damaging (0.936); catalogued as COSV99328980; called by muse, mutect2, varscan2
- TMTC1 | c.448C>G p.L150V (on ENST00000539277 / NM_001193451.2; = p.L42V on NM_175861.3) | Missense Mutation (SNP) | VAF 13/55 reads (24%) | SIFT deleterious (0.01); PolyPhen benign (0.17); catalogued as COSV55478617, COSV99758876; called by muse, mutect2, varscan2
- TRMT1 | c.1161_1162del p.C387Wfs*17 | Frame Shift Del (DEL) | VAF 8/76 reads (11%) | catalogued as rs756963751; called by pindel, varscan2
- TRPM6 | c.5852C>T p.P1951L | Missense Mutation (SNP) | VAF 13/51 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs143161006, COSV100666602; called by muse, mutect2, varscan2
- UBE2L6 | c.377C>T p.A126V | Missense Mutation (SNP) | VAF 39/221 reads (18%) | SIFT deleterious (0.01); PolyPhen benign (0.387); catalogued as COSV99761782; called by muse, mutect2, varscan2
- UBE2O | c.2141T>C p.I714T | Missense Mutation (SNP) | VAF 26/118 reads (22%) | SIFT deleterious (0.04); PolyPhen benign (0.173); catalogued as rs769801871, COSV100084196; called by muse, mutect2, varscan2
- UBN1 | c.552G>C p.K184N | Missense Mutation (SNP) | VAF 19/64 reads (30%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.984); catalogued as COSV52166799, COSV99277527; called by muse, mutect2, varscan2
- VANGL2 | c.674C>A p.A225D | Missense Mutation (SNP) | VAF 19/95 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV100925534, COSV63603989; called by muse, mutect2, varscan2
- VCL | c.1747C>A p.L583I | Missense Mutation (SNP) | VAF 16/115 reads (14%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.982); catalogued as COSV99280486; called by muse, mutect2, varscan2
- VCL | c.1849C>T p.P617S | Missense Mutation (SNP) | VAF 16/98 reads (16%) | SIFT tolerated (0.73); PolyPhen benign (0); catalogued as COSV53007311; called by muse, mutect2, varscan2
- YEATS2 | c.91G>A p.E31K | Missense Mutation (SNP) | VAF 15/56 reads (27%) | SIFT deleterious (0); PolyPhen benign (0.341); catalogued as rs769469597, COSV100527512; called by muse, mutect2, varscan2
- ZC3H4 | c.815C>G p.S272C | Missense Mutation (SNP) | VAF 15/76 reads (20%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.667); catalogued as COSV99451773; called by muse, mutect2, varscan2
- ZSCAN18 | c.1225C>T p.R409C | Missense Mutation (SNP) | VAF 4/10 reads (40%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.586); catalogued as rs1289497381, COSV99559142; called by muse, mutect2, varscan2
- ZSCAN5B | c.542G>A p.R181Q | Missense Mutation (SNP) | VAF 8/37 reads (22%) | SIFT tolerated (0.73); PolyPhen benign (0.007); catalogued as rs1244662861, COSV62839744; called by muse, mutect2, varscan2
- DBH | c.1698_1700del p.N566del | In Frame Del (DEL) | VAF 8/55 reads (15%) | called by pindel, varscan2
- FAT1 | c.9683dup p.V3229Cfs*3 | Frame Shift Ins (INS) | VAF 13/42 reads (31%) | called by mutect2, pindel, varscan2
- FOSL2 | c.603_616del p.P202Afs*52 | Frame Shift Del (DEL) | VAF 16/91 reads (18%) | called by mutect2, pindel, varscan2
- IGKV1-6 | c.140C>A p.A47E | Missense Mutation (SNP) | VAF 35/165 reads (21%) | SIFT deleterious (0.01); PolyPhen benign (0.409); called by muse, mutect2, varscan2
- KMT2B | c.3325dup p.R1109Pfs*4 | Frame Shift Ins (INS) | VAF 14/41 reads (34%) | called by mutect2, pindel, varscan2
- MEDAG | c.540dup p.G181Rfs*3 | Frame Shift Ins (INS) | VAF 13/88 reads (15%) | called by mutect2, pindel, varscan2
- MESP2 | c.766_767del p.Q256Vfs*110 | Frame Shift Del (DEL) | VAF 5/20 reads (25%) | called by mutect2, pindel, varscan2
- PSMC5 | c.997del p.S333Lfs*4 | Frame Shift Del (DEL) | VAF 15/107 reads (14%) | called by mutect2, pindel, varscan2
- RAN | c.291_294del p.Y98Rfs*33 | Frame Shift Del (DEL) | VAF 11/58 reads (19%) | called by pindel, varscan2
- THEM4 | c.437dup p.P147Tfs*15 | Frame Shift Ins (INS) | VAF 14/75 reads (19%) | called by mutect2, pindel, varscan2
- ZBTB22 | c.1252_1256del p.P418Gfs*50 | Frame Shift Del (DEL) | VAF 73/235 reads (31%) | called by mutect2, pindel, varscan2
- ADAMTS18 | c.234C>T p.H78= | Silent (SNP) | VAF 19/322 reads (6%) | catalogued as rs369294701; called by muse, mutect2
- ADCYAP1 | c.372C>T p.D124= | Silent (SNP) | VAF 22/89 reads (25%) | catalogued as rs750712661, COSV99327457; called by muse, mutect2, varscan2
- ALDH1B1 | c.978C>T p.F326= | Silent (SNP) | VAF 9/42 reads (21%) | catalogued as rs746866232, COSV100890891; called by muse, mutect2, varscan2
- ALDH3A2 | c.396G>C p.V132= | Silent (SNP) | VAF 11/71 reads (15%) | catalogued as COSV99449630; called by muse, mutect2, varscan2
- ATP10B | c.1551C>A p.G517= | Silent (SNP) | VAF 7/51 reads (14%) | catalogued as COSV58779495; called by mutect2, varscan2
- BACE1 | c.1125G>A p.T375= | Silent (SNP) | VAF 9/29 reads (31%) | catalogued as rs75519595; called by muse, mutect2, varscan2
- CATSPERD | c.958C>T p.L320= | Silent (SNP) | VAF 14/54 reads (26%) | catalogued as rs781101325, COSV58465994; called by muse, mutect2
- CBARP | c.99C>T p.D33= (on ENST00000382477; = p.D39= on NM_152769.3) | Silent (SNP) | VAF 26/112 reads (23%) | catalogued as rs763428574, COSV99289382; called by muse, varscan2
- CLMN | c.790C>T p.L264= | Silent (SNP) | VAF 6/97 reads (6%) | catalogued as COSV100112118, COSV100112422; called by muse, mutect2
- CTCF | c.1056G>A p.K352= | Silent (SNP) | VAF 20/230 reads (9%) | catalogued as COSV50465937, COSV99864502; called by muse, mutect2
- DDX6 | c.831C>T p.S277= | Silent (SNP) | VAF 19/55 reads (35%) | catalogued as rs376083867; called by muse, mutect2, varscan2
- DIRAS3 | c.204G>A p.P68= | Silent (SNP) | VAF 28/114 reads (25%) | catalogued as rs1414824900, COSV63971264; called by muse, mutect2, varscan2
- DSG1 | c.1707C>T p.I569= | Silent (SNP) | VAF 31/176 reads (18%) | catalogued as COSV99935620; called by muse, mutect2, varscan2
- EIF5 | c.15C>G p.V5= | Silent (SNP) | VAF 35/150 reads (23%) | catalogued as COSV99384672; called by muse, mutect2, varscan2
- EPB41L3 | c.2025C>T p.S675= | Silent (SNP) | VAF 11/54 reads (20%) | catalogued as rs1391239130, COSV100548238; called by muse, mutect2, varscan2
- FOXA2 | c.96C>T p.N32= (on ENST00000377115 / NM_153675.3; = p.N38= on NM_021784.5) | Silent (SNP) | VAF 22/113 reads (19%) | catalogued as COSV101008263; called by muse, mutect2, varscan2
- INTS2 | c.516A>G p.V172= | Silent (SNP) | VAF 7/37 reads (19%) | catalogued as COSV99247829; called by mutect2, varscan2
- LARGE1 | c.1206G>A p.L402= | Silent (SNP) | VAF 15/44 reads (34%) | catalogued as rs982770696, COSV100504722; called by muse, mutect2, varscan2
- LGR4 | c.2490C>T p.I830= | Silent (SNP) | VAF 30/188 reads (16%) | catalogued as COSV100156397; called by muse, mutect2, varscan2
- LMF2 | c.2007C>T p.V669= | Silent (SNP) | VAF 10/36 reads (28%) | catalogued as COSV99327398; called by muse, mutect2
- LY6D | c.378C>T p.P126= | Silent (SNP) | VAF 5/32 reads (16%) | catalogued as COSV100009269, COSV56661027; called by muse, mutect2, varscan2
- MAP4K1 | c.624G>T p.L208= | Silent (SNP) | VAF 16/73 reads (22%) | catalogued as COSV101204145; called by muse, mutect2, varscan2
- MYO16 | c.1056C>T p.A352= | Silent (SNP) | VAF 6/56 reads (11%) | catalogued as COSV99193575; called by muse, mutect2, varscan2
- NCOR2 | c.3447C>T p.T1149= | Silent (SNP) | VAF 13/67 reads (19%) | catalogued as rs373530484; called by muse, mutect2, varscan2
- NFATC2 | c.117G>A p.L39= | Silent (SNP) | VAF 7/41 reads (17%) | catalogued as COSV101043667, COSV101044667; called by muse, mutect2, varscan2
- NOD2 | c.1773C>T p.V591= | Silent (SNP) | VAF 5/29 reads (17%) | catalogued as rs773962188, COSV56049806; called by muse, mutect2, varscan2
- NT5M | c.525C>T p.D175= | Silent (SNP) | VAF 11/51 reads (22%) | catalogued as rs201242235, COSV66519222; called by muse, mutect2, varscan2
- OTOA | c.537C>T p.I179= | Silent (SNP) | VAF 10/55 reads (18%) | catalogued as COSV99623728; called by muse, mutect2, varscan2
- PCDHA4 | c.1353C>T p.N451= | Silent (SNP) | VAF 23/101 reads (23%) | catalogued as rs782636671, COSV63539191; called by muse, mutect2, varscan2
- PGBD4 | c.426G>A p.S142= | Silent (SNP) | VAF 19/87 reads (22%) | catalogued as rs747482228, COSV99854716; called by muse, mutect2, varscan2
- PTK7 | c.1989C>T p.T663= | Silent (SNP) | VAF 25/53 reads (47%) | catalogued as COSV100029882; called by muse, mutect2, varscan2
- SHPRH | c.3234G>A p.L1078= (on ENST00000275233 / NM_001042683.3; = p.L1087= on NM_173082.3) | Silent (SNP) | VAF 16/104 reads (15%) | catalogued as COSV99261392; called by muse, mutect2, varscan2
- SLC32A1 | c.1272C>T p.G424= | Silent (SNP) | VAF 8/33 reads (24%) | catalogued as COSV99461849; called by muse, mutect2, varscan2
- SMPD3 | c.234G>A p.A78= | Silent (SNP) | VAF 5/20 reads (25%) | catalogued as rs147838351; called by muse, mutect2, varscan2
- SNX8 | c.1245C>T p.L415= | Silent (SNP) | VAF 9/49 reads (18%) | catalogued as COSV99770579; called by muse, mutect2, varscan2
- SOX3 | c.432C>T p.N144= | Silent (SNP) | VAF 12/28 reads (43%) | catalogued as rs1220108057; called by muse, mutect2
- SPRR2B | c.207G>A p.P69= | Silent (SNP) | VAF 25/153 reads (16%) | catalogued as rs541636188, COSV58797504; called by muse, mutect2, varscan2
- SYT9 | c.342C>T p.D114= | Silent (SNP) | VAF 15/65 reads (23%) | catalogued as COSV100607617; called by muse, mutect2, varscan2
- TAGLN3 | c.522A>C p.I174= | Silent (SNP) | VAF 23/98 reads (23%) | catalogued as COSV99845289; called by muse, mutect2, varscan2
- TMEM132D | c.276C>T p.V92= | Silent (SNP) | VAF 7/36 reads (19%) | catalogued as COSV70595556; called by muse, mutect2, varscan2
- UBR5 | c.4458C>G p.V1486= | Silent (SNP) | VAF 5/27 reads (19%) | catalogued as COSV99639568; called by muse, mutect2, varscan2
- ZCCHC10 | c.327C>G p.T109= (on ENST00000509437 / NM_001300818.3; = p.T87= on NM_017665.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 14/71 reads (20%) | catalogued as COSV100147854; called by muse, mutect2, varscan2
- PML | c.1710+1498C>G | Intron (SNP) | VAF 65/348 reads (19%) | catalogued as COSV51446436; called by muse, mutect2, varscan2
- SNORD50B | chr6:85677361 C>T | 3'Flank (SNP) | VAF 21/67 reads (31%) | called by muse, mutect2, varscan2
- SSPOP | n.7053C>T | RNA (SNP) | VAF 17/92 reads (18%) | catalogued as rs1438963116, COSV100022177; called by muse, mutect2, varscan2
